Somatic mutation profile of tumor specimen ALCH-B280-TTP1-A (aliquot ALCH-B280-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B280, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.5 years (26,103 days).
Specimen ALCH-B280-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17cab7f1-4bf5-4376-aa29-86f35fe808ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B280-NB1-A (Blood Derived Normal), aliquot ALCH-B280-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/302a8c61-7f19-4cd8-b685-943b0f91dc2d

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH9 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50415316; called by muse, mutect2
- TRIM66 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs867289167; called by muse, mutect2
- B4GALNT4 | c.2098T>C p.W700R | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- HPS3 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LZTS3 | c.1611G>T p.E537D (on ENST00000329152; = p.E491D on NM_001282533.2) | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2
- ROBO2 | c.3872A>C p.H1291P | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENO1 | c.726C>T p.I242= | Silent (SNP) | VAF 28/438 reads (6%) | catalogued as rs926942765, COSV52303655; called by muse, mutect2
- MYH10 | c.2962C>T p.L988= | Silent (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- PITRM1 | c.699G>A p.V233= | Silent (SNP) | VAF 20/300 reads (7%) | called by muse, mutect2
- TRIM65 | c.1095C>T p.P365= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as rs759014791, COSV53934181; called by muse, mutect2
- MCF2 | c.-19G>A | 5'UTR (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- NLGN4Y | c.*1039G>C | 3'UTR (SNP) | VAF 15/140 reads (11%) | catalogued as rs914603689, COSV104410747; called by muse, varscan2
